TCGA case TCGA-OR-A5J9 — Adrenocortical Carcinoma (TCGA-ACC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Adrenal gland; Tissue source site: University of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a53e9117-0a49-40d8-af40-7867370b671a

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: Brazil; Age at index: 22 years; Vital status: Alive.

Diagnoses (2)
1. Adrenal cortical carcinoma (the primary disease): ICD-O-3 morphology code: 8370/3; ICD-10 code: C74.0; Tissue or organ of origin: Cortex of adrenal gland; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 22.4 years (8,175 days); Year of diagnosis: 2010; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,352 days (3.7 years); Ensat clinical m: M0; Ensat pathologic n: N0; Ensat pathologic stage: Stage II; Ensat pathologic t: T2; Weiss assessment findings: Cytoplasm presence <= to 25% / Diffuse Architecture / Mitotic Rate > 5/50 HPF / Necrosis / Nuclear Grade III or IV / Sinusoid Invasion; Weiss assessment score: 6.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Mitotane; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Therapeutic target level: >14 mg/L.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Adrenal cortical carcinoma), site: Lung, NOS. Age at diagnosis: 23.5 years (8,589 days); Days to diagnosis: 414 days (1.1 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (6 entries)
- Day 414 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 414 days (1.1 years); Evidence of progression type: Convincing Image Source.
- Day 1,183 (within 3 months of surgery): Disease response: Tumor Free.
- Days to follow up: 1,183 days (3.2 years); Disease response: With Tumor.
- Day 1,352 (within 3 months of surgery): Disease response: Tumor Free.
- Days to follow up: 1,352 days (3.7 years); Disease response: With Tumor.
- Imaging type: CT Scan; Imaging findings: Normal; Timepoint: Preoperative.

Molecular and laboratory tests
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 6.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-OR-A5J9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 190 mg.
  Slide TCGA-OR-A5J9-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-OR-A5J9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-OR-A5J9-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Pharmaceutical treatment mitotane indicator: Yes; Clinical status within 3 mths surgery: No imaging evidence of disease; Treatment outcome first course: Complete Remission/Response.
- Primary pathology: Submitted tumor site: Adrenal; Histologic diagnosis: Adrenocortical carcinoma- Usual Type; Ct scan preop results: Yes; Lymph nodes examined: No; Mitoses per 50 hpf: 6.
- Primary pathology, Weiss assessment report, Weiss assessment categories: Nuclear grade III IV: Nuclear Grade III or IV Present; Mitotic rate: Mitotic Rate > 5/50 HPF Present; Atypical mitotic figures: Atypical Mitotic Figures Absent; Cytoplasm presence less than equal 25 percent: Cytoplasm presence <= 25% Present; Diffuse architecture: Diffuse Architecture Present; Necrosis: Necrosis Present; Weiss venous invasion: Venous Invasion Absent; Sinusoid invasion: Sinusoid Invasion Present; Invasion of tumor capsule: Invasion of Tumor Capsule Absent.
- Primary pathology, Germline genotype testing report: Molecular studies others performed: No.
- Follow-up form: Lost to follow-up: No; Clinical status within 3 mths surgery: No imaging evidence of disease; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,352 days; disease-specific survival: no event (censored), 1,352 days; disease-free interval: event (new tumor event after initially disease-free), 414 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 414 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-OR-A5J9-01A-11D-A29H-01): tumor purity 0.84, ploidy 2.61, whole-genome doublings 1.
